Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8D9, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8D9-01A (Primary Tumor).

ICD O 3
Thymoma, type AB malignant
8582/3
Site: Thymus C37.9
Q2611.4/4

Operative Procedure:
Thymectomy.

Specimen Received:
Thymus, resection

Final Pathologic Diagnosis:

Thymus, thymectomy:

Thymoma, type AB (see Note).

Tumor size: 4.9 cm

Tumor is limited to thymus and entirely encapsulated.

No invasion is identified.

Pathologic stage: pT1, NX, MX

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:

There is a small focus of necrosis and hyalinization, which may represent a prior biopsy site.

Gross Description:

The specimen is received in formalin with the patient name, labeled "thymus," and consists of a previously inked and sectioned somewhat ragged thymic gland that has dimensions of 12.5 x 10.5 x 3.5 cm. The specimen is remarkable for an encapsulated pink-tan, fleshy and focally fibrous mass that has dimensions of 4.9 x 4.0 x 2.9 cm. There is a small focus of hemorrhage and degeneration with dimensions of 0.8 x 0.6 x 0.6 cm. This mass is confined to within a capsule with the surrounding tissue being freely mobile over it.

Additionally, there is an adherent portion of apparent mesothelium that is possibly consistent with pleura or pericardium. This tissue has dimensions of 4.0 x 3.0 x 0.1 cm. The mass does not grossly appear to involve this tissue. No other focal lesions are identified. There are no lymph nodes identified.

Representative sections are submitted as labeled:

1-5 mass to include associated pleura/pericardium in cassette 4 and degenerated hemorrhagic focus in cassette 5;

6 normal most parenchyma.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

Surgical Pathology Report

Taken:

DOB:

Gender: F

HPA Discrepancy		4
Unusual/Asynchronous Primary Site		

Source: NCI Genomic Data Commons file 54230da5-0124-4258-a7b6-0ce668a832cf (TCGA-X7-A8D9.F9230935-DFDB-4827-B360-D2D14A9C0C94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).